Somatic mutation profile of tumor specimen TCGA-XJ-A9DI-01A (aliquot TCGA-XJ-A9DI-01A-11D-A377-08) from TCGA case TCGA-XJ-A9DI, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-XJ-A9DI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4cba7d90-7815-4901-93bd-3d4b0ed46009.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XJ-A9DI-10A (Blood Derived Normal), aliquot TCGA-XJ-A9DI-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/325d8167-f3f3-4050-91cb-662a8bcaec56

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD7 | c.1603C>T p.Q535* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV101418310; called by muse, mutect2, varscan2
- GTF2H3 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1372098264, COSV99967609; called by muse, mutect2
- MFHAS1 | c.2411G>A p.R804Q | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.778); catalogued as COSV99359700; called by muse, mutect2
- SLC25A28 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1418139775, COSV65125442; called by muse, mutect2
- TAF13 | c.164A>G p.D55G | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.626); catalogued as COSV100615494; called by muse, mutect2
- USF2 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 13/90 reads (14%) | catalogued as COSV99723428; called by muse, mutect2, varscan2
- WNK4 | c.1364T>C p.L455P | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1380072081, COSV99890694; called by mutect2, varscan2
- CYP7A1 | c.21T>A p.I7= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as rs1375898428, COSV100052469; called by muse, mutect2
- MCAT | c.1122G>A p.V374= | Silent (SNP) | VAF 18/238 reads (8%) | catalogued as COSV99295714; called by muse, mutect2
- R3HCC1L | c.591A>G p.A197= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as rs1019476552, COSV100107406; called by muse, mutect2
- TNS3 | c.1695C>T p.P565= | Silent (SNP) | VAF 5/85 reads (6%) | catalogued as COSV100235815; called by muse, mutect2
